Gene-level copy-number profile of tumor specimen HTMCP-03-06-02012-01B from CGCI case HTMCP-03-06-02012, project CGCI-HTMCP-CC (HIV+ Tumor Molecular Characterization Project - Cervical Cancer). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, nonkeratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIIB; Tumor grade: G2; Age at diagnosis: 54.1 years (19,742 days).
Specimen HTMCP-03-06-02012-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 529dbe0c-8761-443d-9a33-69d91ce56834.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HTMCP-03-06-02012-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,233 have no estimate.
https://portal.gdc.cancer.gov/files/82486880-925e-4d67-9070-4062500e4a8c

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 1; copy number 1: 862; copy number 2: 53,558; copy number 3: 3,739; copy number 4: 213; copy number 5: 1; copy number 6: 9; copy number 8: 3; copy number 9: 1; copy number 11: 3.

Homozygous deletions (total copy number 0; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr22:15,635,180–15,644,330, 1 gene: MED15P7.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 17 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:170,357,678–170,396,835, 1 gene, copy number 5: SKIL.
- chr9:61,868,727–61,911,022, 3 genes, copy number 8: AL391987.3, Y_RNA, FAM242E.
- chr16:18,313,294–18,401,940, 9 genes, copy number 6 (within-gene range 4–6): AC126755.3, NPIPA8, AC126755.5, PKD1P4, MIR6511A4, AC126755.4, NPIPA9, PKD1P5, MIR6770-3.
- chr22:15,805,263–15,820,884, 1 gene, copy number 9: BMS1P22.
- chr22:18,906,028–18,947,732, 3 genes, copy number 11 (within-gene range 2–11): DGCR6, AC007326.4, PRODH.

Autosomal genes at a single copy (total copy number 1): 862. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
